Gene-level copy-number profile of tumor specimen ALCH-B3AY-TTP1-A from ALCHEMIST case ALCH-B3AY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.4 years (20,582 days).
Specimen ALCH-B3AY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file db1ef85d-f818-4937-b29f-0888d670a46b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3AY-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/3b41486d-c523-4a59-be77-ae197cfd53aa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 17,824; copy number 2: 33,138; copy number 3: 5,878; copy number 4: 1,539; copy number 5: 4; copy number 6: 6; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:76,190,725–76,195,071, 1 gene (within-gene range 0–2): AP000785.1.
- chr15:64,701,248–64,719,602, 1 gene (within-gene range 0–1): AC100830.1.
- chr17:2,724,411–3,037,741, 5 genes (within-gene range 0–1): CCDC92B, MIR1253, hsa-mir-1253, RAP1GAP2, AC015921.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:140,657,900–141,002,216, 4 genes, copy number 5: PTK2, MIR151A, AC105235.1, RNA5SP278.
- chr15:30,540,093–30,600,647, 6 genes, copy number 6: AC026150.1, GOLGA8Q, RN7SL796P, DNM1P50, ULK4P2, U8.
- chr15:82,339,993–82,349,475, 1 gene, copy number 7: GOLGA6L10.

Autosomal genes at a single copy (total copy number 1): 15,570. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
